Gene-level copy-number profile of tumor specimen TCGA-FI-A3PV-01A from TCGA case TCGA-FI-A3PV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: High Grade; Age at diagnosis: 68.2 years (24,898 days).
Specimen TCGA-FI-A3PV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.33181af3-11a1-463d-b8b4-a8d38ff0bcc6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FI-A3PV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7163655e-e60c-4dcb-b196-07f832767665

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,187; copy number 2: 11,357; copy number 3: 13,877; copy number 4: 22,899; copy number 5: 5,353; copy number 6: 2,248; copy number 7: 951; copy number 8: 547; copy number 9: 216; copy number 10: 3; copy number 11: 70; copy number 12: 14; copy number 13: 31; copy number 15: 4; copy number 22: 24; copy number 36: 6; copy number 37: 15; copy number 46: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FI-A3PV-01A-11D-A227-01): tumor purity 0.67, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 365 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:98,599,314–99,401,326, 20 genes, copy number 9 (within-gene range 5–9): COA5, UNC50, MGAT4A, YWHAQP5, LINC02611, RNU4-84P, CRACDL, RNU7-46P, TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B.
- chr2:99,405,218–99,405,843, 1 gene, copy number 9: AC018690.1.
- chr2:112,275,597–112,340,063, 1 gene, copy number 11 (within-gene range 3–11): ZC3H6.
- chr2:112,346,011–114,420,302, 69 genes, copy number 11 (broad region; genes not listed).
- chr4:65,216,616–71,030,914, 133 genes, copy number 9–12 (broad region; genes not listed).
- chr6:11,154,929–11,382,348, 4 genes, copy number 9 (within-gene range 4–9): AL136139.1, AL139807.1, NEDD9, AL022098.1.
- chr8:8,317,736–8,386,439, 1 gene, copy number 10: PRAG1.
- chr8:65,591,850–68,237,032, 48 genes, copy number 9 (within-gene range 4–9): AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2.
- chr8:68,302,246–69,987,697, 24 genes, copy number 9 (within-gene range 4–9): C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20.
- chr16:15,865,719–15,932,294, 4 genes, copy number 15: CEP20, RNU6-213P, AC130651.1, RPL15P20.
- chr19:29,083,094–30,228,715, 29 genes, copy number 22–36: AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:39,825,350–40,444,335, 31 genes, copy number 13: DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B, AC005614.2, ZNF780A, AC005614.1, VN1R96P, MAP3K10, TTC9B, CCNP, AKT2, AC118344.1, MIR641, RNU6-945P, C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3.

Autosomal genes at a single copy (total copy number 1): 798. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
